Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0G0, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0G0-01A (Primary Tumor).

TSS Patient ID:

Case #: . DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: Breast Cancer Histological description: Infiltrative ductal carcinoma

Date of Procurement Anatomic Site: Right Breast Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: Frozen

Container: cryomold Type of Procurement: Radical mastectomy Grade: 3

T Stage: 2 N Stage: 0 M Stage: 0 Treatment: none

Treatment Details: n/a

Normal Sample

Anatomic Site: Blood Sample Type: Normal Type of Procurement: blood draw

Matrix: Blood Specimen Format: frozen Container: tube

Date of Procurement: .

ICD-O-3

carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 lw
10/21/11

lw 10/21/11		

Source: NCI Genomic Data Commons file 0b09e9e6-535f-423e-a36c-80e76e7bba97 (TCGA-AN-A0G0.08519263-5ADD-4BA3-9BC6-C737ACA7DFE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).